Somatic mutation profile of tumor specimen ALCH-B1K0-TTP1-A (aliquot ALCH-B1K0-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B1K0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.8 years (25,113 days).
Specimen ALCH-B1K0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42b06cc1-0556-41a1-9ca0-fe450685d3f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1K0-NB1-A (Blood Derived Normal), aliquot ALCH-B1K0-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55c0a374-dfb0-45b0-a858-23361d5c1a13

The open-access MAF lists 304 somatic variants for this specimen: 209 protein-altering or splice-affecting, 63 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 63, Nonsense Mutation 17, Intron 11, 3'UTR 9, RNA 7, Frame Shift Del 4, 5'Flank 3, Splice Region 3, Splice Site 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 64/644 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADAMTS2 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as COSV99078639, COSV99280994; called by muse, mutect2
- ADGRG4 | c.3674C>T p.T1225I | Missense Mutation (SNP) | VAF 73/500 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs372556244; called by muse, mutect2, varscan2
- ALKBH8 | c.1922C>A p.T641N | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV52838205; called by muse, mutect2
- ANAPC2 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs751826544; called by muse, mutect2, varscan2
- BANK1 | c.1802C>A p.T601N | Missense Mutation (SNP) | VAF 42/476 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as COSV100536152; called by muse, mutect2
- BRIP1 | c.2120G>C p.R707P | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52007338; called by muse, mutect2
- C1orf35 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs1328447195; called by muse, mutect2
- CAPZA3 | c.824A>G p.D275G | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as rs768925797; called by muse, mutect2
- CDH10 | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 63/616 reads (10%) | catalogued as COSV52574864; called by muse, mutect2, varscan2
- CDH10 | c.334C>A p.H112N | Missense Mutation (SNP) | VAF 70/922 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52569365; called by muse, mutect2
- CHST2 | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as rs559583916, COSV58884701; called by muse, mutect2, varscan2
- CNPY1 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 48/553 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58788683; called by muse, mutect2
- CNTN1 | c.933G>C p.E311D | Missense Mutation (SNP) | VAF 48/684 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100751968; called by muse, mutect2
- COL4A4 | c.4707C>A p.C1569* | Nonsense Mutation (SNP) | VAF 19/211 reads (9%) | catalogued as COSV61631294; called by muse, mutect2
- CORIN | c.2377C>A p.R793S | Missense Mutation (SNP) | VAF 23/333 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs375618006; called by muse, mutect2
- CSAG1 | c.167+5G>T | Splice Region (SNP) | VAF 26/547 reads (5%) | catalogued as COSV63400710; called by muse, mutect2
- DGKZ | c.1621G>A p.G541R (on ENST00000454345 / NM_001105540.2; = p.G353R on NM_003646.4) | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771956773, COSV100552143, COSV58988416; called by muse, mutect2
- DNAH3 | c.4175G>T p.G1392V | Missense Mutation (SNP) | VAF 32/688 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1212658088, COSV54525443; called by muse, mutect2
- DNAH6 | c.9709G>A p.E3237K | Missense Mutation (SNP) | VAF 14/384 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV52874908; called by muse, mutect2
- DPYSL4 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs1462095937; called by muse, mutect2
- EHD4 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs1450883199; called by muse, mutect2, varscan2
- EPB41L5 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 28/305 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55353733; called by muse, mutect2
- FAM47A | c.2288G>T p.W763L | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60496680; called by muse, mutect2, varscan2
- FAM81B | c.787-2A>C p.X263_splice | Splice Site (SNP) | VAF 75/635 reads (12%) | catalogued as COSV99353311; called by muse, mutect2, varscan2
- GRM5 | c.2500C>A p.R834S | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59597532; called by muse, mutect2
- GSTK1 | c.85T>C p.Y29H | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1274353462; called by muse, mutect2
- HDAC9 | c.1407G>C p.Q469H | Missense Mutation (SNP) | VAF 77/706 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as COSV101286020; called by muse, mutect2, varscan2
- HMCN1 | c.6481-1G>C p.X2161_splice | Splice Site (SNP) | VAF 32/682 reads (5%) | catalogued as COSV54927003; called by muse, mutect2
- IQGAP2 | c.2447G>A p.R816K | Missense Mutation (SNP) | VAF 54/560 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as COSV57175537; called by muse, mutect2
- KCND2 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.234); catalogued as rs1464901287, COSV58580353; called by muse, mutect2
- KEAP1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 62/732 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50268680, COSV50336542; called by muse, mutect2
- KHDRBS2 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 28/319 reads (9%) | catalogued as rs1277186373, COSV104385027; called by muse, mutect2
- KLHL1 | c.1661C>A p.P554H | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as COSV100916948, COSV64767242; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2470G>T p.G824W | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51724137, COSV51727615; called by muse, mutect2, varscan2
- MYO9B | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 150/824 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.024); catalogued as rs1291130570; called by muse, mutect2
- NIPBL | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 123/1032 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); catalogued as rs200692598, COSV99239140; ClinVar: uncertain significance; called by mutect2, varscan2
- NLRP14 | c.1849G>T p.V617L | Missense Mutation (SNP) | VAF 17/395 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55071295; called by muse, mutect2
- OPRK1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200672427, COSV55568081; called by muse, mutect2, varscan2
- OR2T10 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 50/600 reads (8%) | catalogued as rs752785822; called by muse, mutect2
- OSBPL6 | c.1931G>A p.G644E | Missense Mutation (SNP) | VAF 18/413 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV51918831; called by muse, mutect2
- P2RX6 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs1169171403, COSV53035713; called by muse, mutect2
- PCDH11X | c.501C>G p.D167E | Missense Mutation (SNP) | VAF 67/484 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100015760; called by muse, mutect2, varscan2
- PGLYRP2 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52996809; called by muse, mutect2, varscan2
- PROKR2 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 42/546 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.317); catalogued as rs576243101, COSV54085395; called by muse, mutect2
- PSD3 | c.2276G>T p.G759V (on ENST00000440756; = p.G758V on NM_015310.4) | Missense Mutation (SNP) | VAF 48/403 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as COSV54079521; called by muse, mutect2, varscan2
- PTGES2 | c.407G>C p.R136P | Missense Mutation (SNP) | VAF 55/451 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV52969318; called by muse, mutect2, varscan2
- RADIL | c.2181C>A p.S727R | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV68198900; called by muse, mutect2
- RAPH1 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 48/579 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as COSV57356162; called by muse, mutect2
- SCN1A | c.5173G>A p.G1725S (on ENST00000303395 / NM_001202435.3; = p.G1714S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/872 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM096167; called by muse, mutect2
- SERPINB12 | c.617C>A p.T206K | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54032695; called by muse, mutect2
- SLC16A1 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 109/1048 reads (10%) | catalogued as rs766172980, COSV63709047; called by muse, mutect2, varscan2
- SLC17A1 | c.992T>G p.L331R | Missense Mutation (SNP) | VAF 44/483 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1455293838, COSV55082602; called by muse, mutect2
- SPAM1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.169); catalogued as rs770976726, COSV56141288; called by muse, mutect2
- SPTBN4 | c.6616G>A p.A2206T | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1022846614; called by muse, mutect2
- SYTL5 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); catalogued as COSV52897982, COSV52905446; called by muse, mutect2, varscan2
- TCEAL8 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as COSV100749843; called by muse, mutect2, varscan2
- TEX33 | c.171C>A p.S57R | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.076); catalogued as rs934397197; called by muse, mutect2, varscan2
- THAP11 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.342); catalogued as rs150290499; called by muse, mutect2
- THBS1 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.133); catalogued as COSV52950247; called by muse, mutect2
- TPBGL | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0.02); catalogued as rs1325006424; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2049G>C p.W683C | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs745336901; called by muse, mutect2
- TULP3 | c.1240T>C p.F414L | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68117337; called by muse, mutect2
- VN1R4 | c.799G>C p.V267L | Missense Mutation (SNP) | VAF 55/672 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.065); catalogued as COSV60805277; called by muse, mutect2
- VN1R4 | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 42/611 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV60805922; called by muse, mutect2
- WIZ | c.4709G>A p.R1570H (on ENST00000673675 / NM_001371589.1; = p.R475H on NM_021241.3) | Missense Mutation (SNP) | VAF 34/463 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs763043704, COSV54604784; called by muse, mutect2
- XIRP2 | c.2941G>T p.E981* (on ENST00000628543; = p.E1156* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 24/417 reads (6%) | catalogued as COSV54712037; called by muse, mutect2
- ZC2HC1C | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 37/834 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1163919971; called by muse, mutect2
- ZNF606 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs139491730; called by muse, mutect2, varscan2
- ZNF625 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs1348782828; called by muse, mutect2
- ZNF831 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV64043553; called by muse, mutect2
- ZNF99 | c.1541G>T p.C514F | Missense Mutation (SNP) | VAF 25/449 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68055605; called by muse, mutect2
- ABCA2 | c.6488G>T p.C2163F (on ENST00000614293; = p.C2133F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACVR2A | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 37/605 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.395); called by muse, mutect2
- ADCY1 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2
- ADGRE3 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 37/573 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2
- ADGRL2 | c.2346T>G p.N782K (on ENST00000370717 / NM_001366005.1; = p.N769K on NM_012302.4) | Missense Mutation (SNP) | VAF 66/682 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.137); called by muse, mutect2
- ADGRV1 | c.13940A>G p.E4647G | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- ALDH1A2 | c.1020C>A p.S340R | Missense Mutation (SNP) | VAF 29/572 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKFN1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 40/678 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.014); called by muse, mutect2
- ANKRD12 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- APBA2 | c.413T>A p.V138E | Missense Mutation (SNP) | VAF 22/564 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.346); called by muse, mutect2
- ARHGAP22 | c.647C>A p.P216Q | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ASXL3 | c.6038C>T p.A2013V | Missense Mutation (SNP) | VAF 25/626 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); called by muse, mutect2
- ATP8A1 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 28/424 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2
- C8G | c.596A>T p.E199V | Missense Mutation (SNP) | VAF 15/476 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2
- CACNA2D1 | c.2763G>T p.V921= (on ENST00000356253 / NM_001366867.1; = p.V909= on NM_000722.4) | Splice Region (SNP) | VAF 70/1148 reads (6%) | called by muse, mutect2
- CADM1 | c.826G>C p.V276L | Missense Mutation (SNP) | VAF 32/828 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- CADPS | c.2233G>C p.D745H | Missense Mutation (SNP) | VAF 52/555 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDH7 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 45/676 reads (7%) | called by muse, mutect2
- CDK5 | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CELSR1 | c.8983G>A p.V2995M | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEP295 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); called by muse, mutect2
- CEP85L | c.1799T>C p.L600S | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHD8 | c.4543A>G p.K1515E (on ENST00000646647 / NM_001170629.2; = p.K1236E on NM_020920.4) | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- CNTNAP4 | c.3683A>G p.D1228G | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- CNTNAP5 | c.81C>G p.N27K | Missense Mutation (SNP) | VAF 43/545 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.091); called by muse, mutect2
- COL5A2 | c.3640C>G p.P1214A | Missense Mutation (SNP) | VAF 32/446 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); called by muse, mutect2
- CRB2 | c.2531A>T p.Q844L | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CSPG4 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DIRAS2 | c.324A>T p.K108N | Missense Mutation (SNP) | VAF 98/1046 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DMD | c.9852G>A p.W3284* | Nonsense Mutation (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2
- DNAH5 | c.8389C>G p.L2797V | Missense Mutation (SNP) | VAF 60/853 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2
- DNAJC24 | c.163T>G p.C55G | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.116); called by muse, mutect2
- EBF3 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 19/476 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- ELOA2 | c.1268C>A p.S423Y | Missense Mutation (SNP) | VAF 65/901 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- EPHA2 | c.1406A>G p.Y469C | Missense Mutation (SNP) | VAF 44/664 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FADS1 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); called by muse, mutect2
- FAT3 | c.3778C>A p.Q1260K | Missense Mutation (SNP) | VAF 26/698 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.671); called by muse, mutect2
- FBXW8 | c.1473T>A p.Y491* (on ENST00000309909; = p.Y529* on NM_012174.1) | Nonsense Mutation (SNP) | VAF 25/265 reads (9%) | called by muse, mutect2
- FEZ1 | c.362G>T p.W121L | Missense Mutation (SNP) | VAF 33/902 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2
- FNDC1 | c.3275_3299del p.R1092Pfs*141 | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | called by mutect2, pindel
- FREM2 | c.5065A>T p.R1689* | Nonsense Mutation (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- FZD9 | c.1734G>A p.M578I | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.014); called by muse, mutect2
- GAREM2 | c.341C>G p.P114R | Missense Mutation (SNP) | VAF 45/528 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GH2 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 62/1122 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GIGYF2 | c.2415del p.R805Sfs*57 | Frame Shift Del (DEL) | VAF 62/704 reads (9%) | called by mutect2, pindel
- GLI3 | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 49/1203 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2
- GLUD1 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 43/748 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GPR87 | c.110A>T p.H37L | Missense Mutation (SNP) | VAF 155/478 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HECTD4 | c.1483C>G p.L495V | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2
- HGH1 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 40/1076 reads (4%) | called by muse, mutect2
- HLA-DOA | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HSPBAP1 | c.1260G>C p.K420N | Missense Mutation (SNP) | VAF 80/946 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.038); called by muse, mutect2
- HTR5A | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 38/706 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- IGHV3-30 | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 89/1550 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.103); called by muse, mutect2
- INF2 | c.3166G>T p.G1056C | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2
- IRS2 | c.3566G>T p.G1189V | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.069); called by muse, mutect2
- KCNA4 | c.1704C>A p.H568Q | Missense Mutation (SNP) | VAF 30/565 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2
- KCNA4 | c.564G>T p.E188D | Missense Mutation (SNP) | VAF 25/443 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2
- KCNC2 | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); called by muse, mutect2
- KRT27 | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- L1CAM | c.2206A>G p.K736E | Missense Mutation (SNP) | VAF 69/427 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- LPCAT1 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LRRC52 | c.411C>A p.H137Q | Missense Mutation (SNP) | VAF 126/1364 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.024); called by muse, mutect2
- MAGEC2 | c.308G>C p.C103S | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAGEE2 | c.1225G>T p.G409C | Missense Mutation (SNP) | VAF 31/260 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP2 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.021); called by muse, mutect2
- MCF2L2 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 122/606 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- MGAT1 | c.1163A>G p.Y388C | Missense Mutation (SNP) | VAF 38/412 reads (9%) | PolyPhen probably damaging (1); called by muse, mutect2
- MORC1 | c.315T>G p.S105R | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MPDZ | c.725C>A p.T242K | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MYH6 | c.4663C>A p.H1555N | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.201); called by muse, mutect2
- MYO9B | c.155T>A p.I52N | Missense Mutation (SNP) | VAF 146/820 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- NCKAP1L | c.3301C>A p.L1101M | Missense Mutation (SNP) | VAF 38/439 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.694); called by muse, mutect2
- NCL | c.1574A>T p.Y525F | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.174); called by muse, mutect2
- NECAB3 | c.397A>G p.R133G | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- OAS3 | c.1727A>T p.E576V | Missense Mutation (SNP) | VAF 45/668 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2
- OR2C3 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 36/713 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2
- OR4K14 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 32/656 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR4N2 | c.247G>T p.V83L | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- OR5L1 | c.352A>T p.M118L | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- OR6N1 | c.353T>A p.M118K | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- OSBPL6 | c.2085A>T p.R695S | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2
- P2RX2 | c.1201C>A p.H401N (on ENST00000343948 / NM_170683.4; = p.H303N on NM_012226.5) | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.813); called by muse, mutect2
- PDE4A | c.1357G>T p.A453S (on ENST00000380702 / NM_001111307.2; = p.A214S on NM_006202.3) | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- PHEX | c.1498G>T p.A500S | Missense Mutation (SNP) | VAF 65/413 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHRF1 | c.1705C>T p.P569S (on ENST00000264555 / NM_001286581.2; = p.P568S on NM_020901.4) | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2
- PRKD1 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 91/1008 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.052); called by muse, mutect2
- PSAPL1 | c.1097G>T p.C366F | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- PSMC1 | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 41/364 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- PTCH1 | c.3450-4C>T | Splice Region (SNP) | VAF 90/928 reads (10%) | called by muse, mutect2
- PTPRC | c.3655C>T p.Q1219* | Nonsense Mutation (SNP) | VAF 56/664 reads (8%) | called by muse, mutect2
- PTPRF | c.3600G>T p.L1200F | Missense Mutation (SNP) | VAF 40/519 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2
- PWWP3B | c.128C>A p.S43* | Nonsense Mutation (SNP) | VAF 18/174 reads (10%) | called by muse, mutect2, varscan2
- REPS1 | c.1580G>T p.G527V (on ENST00000450536 / NM_001286611.2; = p.G526V on NM_031922.4) | Missense Mutation (SNP) | VAF 41/479 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.518); called by muse, mutect2
- RET | c.556C>A p.H186N | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.781); called by muse, mutect2
- RGS19 | c.350T>C p.M117T | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RYR1 | c.13077G>T p.W4359C | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.737); called by muse, mutect2
- SBF2 | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- SFMBT2 | c.1158C>G p.H386Q | Missense Mutation (SNP) | VAF 12/359 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- SKIL | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.297); called by muse, mutect2
- SLC16A3 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2
- SLC33A1 | c.1087A>T p.I363F | Missense Mutation (SNP) | VAF 36/548 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- SLC38A5 | c.586del p.Y196Tfs*7 | Frame Shift Del (DEL) | VAF 41/286 reads (14%) | called by mutect2, pindel, varscan2
- SLC45A2 | c.917T>G p.L306R | Missense Mutation (SNP) | VAF 124/1116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SLC4A4 | c.922G>A p.A308T (on ENST00000264485 / NM_001098484.3; = p.A264T on NM_003759.4) | Missense Mutation (SNP) | VAF 50/772 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2
- SRGAP3 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SSNA1 | c.20C>A p.A7E | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2
- ST3GAL6 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0.09); called by muse, mutect2
- SVOPL | c.968C>T p.T323I (on ENST00000419765; = p.T171I on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/1092 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- SYNE1 | c.25852C>T p.Q8618* (on ENST00000367255 / NM_182961.4; = p.Q8570* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 60/889 reads (7%) | called by muse, mutect2
- SYNE2 | c.16465G>T p.A5489S | Missense Mutation (SNP) | VAF 23/410 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- SYT16 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 92/600 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- TACR1 | c.1177A>T p.K393* | Nonsense Mutation (SNP) | VAF 40/332 reads (12%) | called by muse, varscan2
- TBX22 | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); called by muse, mutect2
- TCHH | c.5209C>T p.Q1737* | Nonsense Mutation (SNP) | VAF 35/444 reads (8%) | called by muse, mutect2
- TEX13C | c.1862C>A p.A621D | Missense Mutation (SNP) | VAF 76/531 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, varscan2
- TMEM119 | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TMEM132B | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 44/585 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- TMEM132C | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 33/489 reads (7%) | called by muse, mutect2
- TRAF6 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 29/724 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.314); called by muse, mutect2
- TRPV6 | c.513C>G p.N171K | Missense Mutation (SNP) | VAF 20/345 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2
- TTLL5 | c.3170A>T p.Q1057L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2
- TTN | c.31514C>G p.A10505G (on ENST00000591111; = p.A9578G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/282 reads (8%) | PolyPhen benign (0); called by muse, mutect2
- ULBP1 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.636); called by muse, mutect2
- VBP1 | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- VN1R4 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 34/566 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); called by muse, mutect2
- VSTM2A | c.95_107del p.F32* | Frame Shift Del (DEL) | VAF 76/882 reads (9%) | called by mutect2, pindel
- VSX2 | c.59G>T p.S20I | Missense Mutation (SNP) | VAF 20/535 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2
- WSCD2 | c.839G>A p.C280Y | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZC3H6 | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 55/667 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- ZNF106 | c.3245A>G p.Q1082R | Missense Mutation (SNP) | VAF 48/628 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- ZNF135 | c.72C>A p.S24R | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- ZNF286A | c.528G>T p.M176I | Missense Mutation (SNP) | VAF 44/616 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- ZNF716 | c.835A>T p.S279C | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.229); called by muse, mutect2
- ZNF732 | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 42/375 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZNF835 | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); called by muse, mutect2
- ZNF98 | c.887G>A p.C296Y | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); called by mutect2, varscan2
- ABCC9 | c.1086T>A p.L362= | Silent (SNP) | VAF 54/569 reads (9%) | called by muse, mutect2
- ANKRD35 | c.387C>T p.S129= | Silent (SNP) | VAF 49/358 reads (14%) | called by muse, mutect2, varscan2
- BACH2 | c.1974C>T p.I658= | Silent (SNP) | VAF 55/716 reads (8%) | catalogued as rs1363022777; called by muse, mutect2
- BSX | c.696G>T p.V232= | Silent (SNP) | VAF 18/233 reads (8%) | catalogued as rs770005772; called by muse, mutect2
- CCKBR | c.942G>T p.P314= | Silent (SNP) | VAF 15/226 reads (7%) | catalogued as COSV58099460, COSV58102623; called by muse, mutect2
- CD177 | c.1029C>A p.T343= | Silent (SNP) | VAF 17/222 reads (8%) | called by muse, mutect2
- DEDD | c.211C>T p.L71= | Silent (SNP) | VAF 54/645 reads (8%) | catalogued as rs868587185; called by muse, mutect2
- DICER1 | c.4743T>C p.L1581= | Silent (SNP) | VAF 79/626 reads (13%) | called by muse, mutect2, varscan2
- DNAH7 | c.7365A>T p.I2455= | Silent (SNP) | VAF 76/1086 reads (7%) | called by muse, mutect2
- DSG4 | c.282A>T p.R94= | Silent (SNP) | VAF 47/621 reads (8%) | called by muse, mutect2
- DYRK1B | c.1359G>T p.A453= | Silent (SNP) | VAF 18/213 reads (8%) | called by muse, mutect2
- ECI2 | c.432G>T p.V144= (on ENST00000380118 / NM_206836.3; = p.V114= on NM_006117.2) | Silent (SNP) | VAF 54/750 reads (7%) | catalogued as rs748334286; called by muse, mutect2
- EXD3 | c.408G>A p.R136= | Silent (SNP) | VAF 16/359 reads (4%) | called by muse, mutect2
- EXOC6B | c.2166G>C p.T722= | Silent (SNP) | VAF 72/892 reads (8%) | called by muse, mutect2
- FAM135B | c.4158G>T p.V1386= | Silent (SNP) | VAF 82/969 reads (8%) | called by muse, mutect2
- FAM47B | c.624G>A p.V208= | Silent (SNP) | VAF 55/303 reads (18%) | called by muse, mutect2, varscan2
- FAT3 | c.4173C>T p.T1391= | Silent (SNP) | VAF 14/345 reads (4%) | called by muse, mutect2
- GABRG2 | c.1089G>C p.R363= (on ENST00000361925 / NM_001375343.1; = p.R323= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 104/1092 reads (10%) | called by muse, mutect2
- GLRA2 | c.922C>T p.L308= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as COSV54349435; called by muse, mutect2, varscan2
- GTF3C1 | c.159G>T p.T53= | Silent (SNP) | VAF 30/340 reads (9%) | called by muse, mutect2
- HAO1 | c.163C>A p.R55= | Silent (SNP) | VAF 42/480 reads (9%) | catalogued as COSV66491549; called by muse, mutect2
- HELZ2 | c.5205C>T p.A1735= (on ENST00000467148 / NM_001037335.2; = p.A1166= on NM_033405.3) | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as rs758143305; called by muse, mutect2
- HLA-DQB2 | c.6T>G p.A2= | Silent (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
- IFT172 | c.1818C>A p.G606= | Silent (SNP) | VAF 42/391 reads (11%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.189G>A p.Q63= | Silent (SNP) | VAF 24/746 reads (3%) | catalogued as rs1341450419; called by muse, mutect2
- KCNA3 | c.1416C>A p.I472= | Silent (SNP) | VAF 48/744 reads (6%) | catalogued as COSV63901859; called by muse, mutect2
- KCNA4 | c.1455C>T p.L485= | Silent (SNP) | VAF 22/469 reads (5%) | called by muse, mutect2
- LRRFIP1 | c.609A>G p.E203= (on ENST00000392000 / NM_001137552.2; = p.E179= on NM_004735.4) | Silent (SNP) | VAF 43/277 reads (16%) | called by muse, mutect2, varscan2
- MAPKAPK5 | c.435G>T p.A145= | Silent (SNP) | VAF 24/205 reads (12%) | catalogued as COSV73411111; called by muse, mutect2, varscan2
- MUC12 | c.1830C>A p.P610= (on ENST00000379442; = p.P467= on NM_001164462.1) | Silent (SNP) | VAF 59/629 reads (9%) | called by muse, mutect2
- NEUROD4 | c.9A>G p.K3= | Silent (SNP) | VAF 10/212 reads (5%) | catalogued as COSV99670112; called by muse, mutect2
- NKD2 | c.717G>A p.E239= | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as COSV56892035; called by muse, mutect2
- NLGN1 | c.1869C>A p.T623= | Silent (SNP) | VAF 117/855 reads (14%) | catalogued as COSV64350740; called by muse, mutect2, varscan2
- NPHS2 | c.522A>T p.I174= | Silent (SNP) | VAF 84/1135 reads (7%) | catalogued as rs1160017738; called by muse, mutect2
- NPSR1 | c.693C>T p.G231= | Silent (SNP) | VAF 31/511 reads (6%) | catalogued as COSV100706353; called by muse, mutect2
- NXPE1 | c.1113G>A p.L371= (on ENST00000424269; = p.L229= on NM_152315.5) | Silent (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2
- NXPE1 | c.960T>G p.T320= (on ENST00000424269; = p.T178= on NM_152315.5) | Silent (SNP) | VAF 36/494 reads (7%) | catalogued as COSV99320790; called by muse, mutect2
- OR8K5 | c.127C>T p.L43= | Silent (SNP) | VAF 20/682 reads (3%) | catalogued as COSV57888782; called by muse, mutect2
- OTOGL | c.6048A>T p.P2016= (on ENST00000547103; = p.P2007= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/460 reads (4%) | called by muse, mutect2
- PCLO | c.6156A>G p.T2052= | Silent (SNP) | VAF 44/485 reads (9%) | called by muse, mutect2
- PHF3 | c.4125A>G p.A1375= | Silent (SNP) | VAF 48/719 reads (7%) | called by muse, mutect2
- PLCL2 | c.3303C>A p.G1101= (on ENST00000615277 / NM_001144382.2; = p.G975= on NM_015184.5) | Silent (SNP) | VAF 38/475 reads (8%) | called by muse, mutect2
- PLEKHA6 | c.1219C>A p.R407= | Silent (SNP) | VAF 34/464 reads (7%) | catalogued as COSV55340632; called by muse, mutect2
- PSEN1 | c.801A>T p.P267= | Silent (SNP) | VAF 41/862 reads (5%) | called by muse, mutect2
- RFPL2 | c.453C>A p.I151= | Silent (SNP) | VAF 22/530 reads (4%) | called by muse, mutect2
- RP1 | c.4114C>T p.L1372= | Silent (SNP) | VAF 26/544 reads (5%) | catalogued as COSV99608678; called by muse, mutect2
- SHISA8 | c.372C>T p.I124= (on ENST00000457093; = p.I157= on NM_001207020.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- SLC15A4 | c.474C>T p.F158= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- SLC9A3 | c.1248G>C p.G416= | Silent (SNP) | VAF 40/548 reads (7%) | called by muse, mutect2
- SRGAP1 | c.831G>T p.L277= | Silent (SNP) | VAF 42/407 reads (10%) | catalogued as COSV61894949; called by muse, mutect2, varscan2
- SRGAP3 | c.2667T>A p.A889= | Silent (SNP) | VAF 18/169 reads (11%) | called by muse, mutect2, varscan2
- STK10 | c.309C>T p.D103= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as rs774171206, COSV99452176; called by muse, mutect2, varscan2
- TERT | c.2481G>A p.Q827= | Silent (SNP) | VAF 26/230 reads (11%) | catalogued as rs915422897; called by muse, mutect2, varscan2
- TNFRSF21 | c.1515A>G p.E505= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- TRIM15 | c.198A>C p.A66= | Silent (SNP) | VAF 24/345 reads (7%) | called by muse, mutect2
- UPF1 | c.1824C>T p.A608= (on ENST00000599848 / NM_001297549.2; = p.A597= on NM_002911.4) | Silent (SNP) | VAF 7/171 reads (4%) | called by muse, mutect2
- USP40 | c.313C>T p.L105= | Silent (SNP) | VAF 81/496 reads (16%) | catalogued as rs1326782973; called by muse, mutect2, varscan2
- VAX1 | c.480C>A p.G160= | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- WWC3 | c.2604T>C p.D868= | Silent (SNP) | VAF 27/148 reads (18%) | called by muse, varscan2
- ZIC4 | c.507C>A p.A169= | Silent (SNP) | VAF 282/1088 reads (26%) | catalogued as COSV67170468, COSV67172242; called by muse, mutect2, varscan2
- ZNF407 | c.2781C>T p.S927= | Silent (SNP) | VAF 34/498 reads (7%) | called by muse, mutect2
- ZNF484 | c.1986A>G p.K662= | Silent (SNP) | VAF 14/322 reads (4%) | catalogued as COSV100214940; called by muse, mutect2
- ZNF729 | c.3141C>A p.P1047= | Silent (SNP) | VAF 20/350 reads (6%) | catalogued as rs1246314639; called by muse, mutect2
- AC011525.1 | n.931A>C | RNA (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- AC034105.1 | n.94A>T | RNA (SNP) | VAF 59/585 reads (10%) | called by muse, mutect2, varscan2
- AMH | c.*25C>A | 3'UTR (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- CCDC159 | c.490+10T>A | Intron (SNP) | VAF 28/302 reads (9%) | called by muse, mutect2
- CCDC74B | c.250+115G>T | Intron (SNP) | VAF 24/353 reads (7%) | called by muse, mutect2
- CD8A | c.*651A>T | 3'UTR (SNP) | VAF 50/513 reads (10%) | called by muse, mutect2, varscan2
- COX7C | c.*28-15G>T | Intron (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- CR1 | c.487+15168G>A | Intron (SNP) | VAF 115/1112 reads (10%) | catalogued as COSV65463421; called by muse, mutect2, varscan2
- CRHR2 | chr7:30686404 G>C | 5'Flank (SNP) | VAF 10/187 reads (5%) | called by muse, mutect2
- DDX41 | c.*619C>T | 3'UTR (SNP) | VAF 25/278 reads (9%) | catalogued as rs1329727523, COSV99043136; called by muse, mutect2
- FBLIM1 | c.890+20A>G | Intron (SNP) | VAF 24/216 reads (11%) | called by muse, mutect2
- FER1L4 | n.3512G>T | RNA (SNP) | VAF 31/294 reads (11%) | called by muse, mutect2, varscan2
- FMNL2 | c.3169+2530T>C | Intron (SNP) | VAF 50/742 reads (7%) | catalogued as rs1398528139; called by muse, mutect2
- GCK | c.-6G>T | 5'UTR (SNP) | VAF 30/764 reads (4%) | called by muse, mutect2
- HERC2P2 | n.345G>T | RNA (SNP) | VAF 34/624 reads (5%) | catalogued as rs1425040556; called by muse, mutect2
- HMGB1P1 | n.355G>A | RNA (SNP) | VAF 61/853 reads (7%) | called by muse, mutect2
- MID1 | c.1286-25G>A | Intron (SNP) | VAF 53/373 reads (14%) | called by muse, mutect2, varscan2
- MOCS1 | c.*857G>T | 3'UTR (SNP) | VAF 201/1407 reads (14%) | called by muse, mutect2, varscan2
- MUC19 | n.5288G>T | RNA (SNP) | VAF 36/498 reads (7%) | called by muse, mutect2
- MZT2B | c.319+1060C>G | Intron (SNP) | VAF 28/394 reads (7%) | catalogued as rs948303059; called by muse, mutect2
- OSCAR | c.*349del | 3'UTR (DEL) | VAF 24/248 reads (10%) | catalogued as rs1193199277, COSV52928583; called by mutect2, pindel
- PNISR | c.277+243G>T | Intron (SNP) | VAF 58/895 reads (6%) | called by muse, mutect2
- POTEC | c.1126+1529G>T | Intron (SNP) | VAF 48/638 reads (8%) | called by muse, mutect2
- RBM14 | c.338-279A>T | Intron (SNP) | VAF 29/544 reads (5%) | called by muse, mutect2
- RBM8A | c.*1617G>C | 3'UTR (SNP) | VAF 151/1195 reads (13%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159051 G>T | 5'Flank (SNP) | VAF 26/245 reads (11%) | called by muse, mutect2, varscan2
- SLC6A13 | c.*37T>C | 3'UTR (SNP) | VAF 29/283 reads (10%) | called by muse, mutect2
- SPAG8 | c.*919G>T | 3'UTR (SNP) | VAF 58/594 reads (10%) | called by muse, mutect2
- SPATA31C1 | n.2749A>C | RNA (SNP) | VAF 30/646 reads (5%) | called by muse, mutect2
- TAZ | c.*353G>A | 3'UTR (SNP) | VAF 54/256 reads (21%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.-16C>T | 5'UTR (SNP) | VAF 6/52 reads (12%) | catalogued as rs1251479283; called by muse, mutect2
- ZNF205 | chr16:3110861 G>C | 5'Flank (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
